Somatic mutation profile of tumor specimen TCGA-RY-A845-01A (aliquot TCGA-RY-A845-01A-11D-A36O-08) from TCGA case TCGA-RY-A845, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 40.0 years (14,617 days).
Specimen TCGA-RY-A845-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf164ff2-da84-46d3-8318-be6971e9c696.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RY-A845-10A (Blood Derived Normal), aliquot TCGA-RY-A845-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62882f82-82e9-4639-ac30-c1b2a5609492

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as rs587782197, COSV52676080, COSV52724970, COSV52728973; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACCS | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs373138553, COSV99772928; called by muse, mutect2, varscan2
- AL645922.1 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs377291549, COSV54960511; called by muse, mutect2, varscan2
- CTNNA3 | c.1091A>G p.D364G | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as rs753966151, COSV101046314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAPK1 | c.371T>A p.L124H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100801109; called by muse, mutect2
- FAM193B | c.1666C>G p.P556A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.061); catalogued as rs1256558001, COSV100286398; called by muse, mutect2, varscan2
- FLCN | c.1246A>G p.N416D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV99550125; called by muse, mutect2
- GDPD2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV100978552; called by muse, mutect2, varscan2
- H4C12 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.282); catalogued as COSV100694746; called by muse, mutect2, varscan2
- HIP1 | c.2829C>A p.N943K | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100416974, COSV61189807; called by muse, mutect2
- IAPP | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.185); catalogued as rs779084862, COSV99556973; called by muse, mutect2, varscan2
- MUC16 | c.31801A>T p.I10601F | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV101198314; called by muse, mutect2, varscan2
- OR12D2 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as COSV65829180; called by muse, mutect2
- PASD1 | c.2035A>G p.T679A | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs773194276, COSV100949105; called by muse, mutect2, varscan2
- PIGA | c.1103C>G p.S368* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | catalogued as COSV100363360, COSV61238171; called by muse, mutect2, varscan2
- SCNN1G | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100263832; called by muse, mutect2
- SIRT5 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1479817968, COSV63080688; called by muse, mutect2, varscan2
- SRBD1 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs549462688, COSV99764709; called by muse, mutect2
- TBCC | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs1201429767, COSV99773934; called by muse, mutect2, varscan2
- TEC | c.274T>C p.F92L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101202546; called by muse, mutect2, varscan2
- URB2 | c.458T>A p.L153H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99270683; called by muse, mutect2, varscan2
- CRIM1 | c.1641T>C p.Y547= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV99752494; called by muse, mutect2
- HSD17B2 | c.657C>T p.S219= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV52274431, COSV99556433; called by muse, mutect2
- NEURL4 | c.2703G>A p.K901= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100222704; called by muse, mutect2, varscan2
- SCN10A | c.579T>C p.D193= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV101479256; called by muse, mutect2, varscan2
- ZBTB2 | c.877C>T p.L293= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV100287501; called by muse, mutect2, varscan2
